Somatic mutation profile of tumor specimen 0DKPWT from CCDI case PBBXUP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Dead; Primary diagnosis: Clear cell sarcoma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 15.2 years (5,534 days).
Specimen 0DKPWT: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e9d596b3-08fd-4ba0-9e34-e5003d395f22.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DKPWA (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dbc12556-f085-43fe-97b8-9584a0450365

The open-access MAF lists 23 somatic variants for this specimen: 13 protein-altering or splice-affecting, 4 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 4, 5'UTR 3, Nonsense Mutation 2, 3'UTR 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CNTN5 | c.1210G>T p.G404W | Missense Mutation (SNP) | VAF 40/1432 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV99680000; called by muse, mutect2
- FAM184A | c.2364C>G p.H788Q | Missense Mutation (SNP) | VAF 390/1746 reads (22%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as rs753992608; called by mutect2, varscan2
- NR1D1 | c.496T>C p.Y166H | Missense Mutation (SNP) | VAF 390/1086 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1309973163; called by muse, mutect2, varscan2
- TNK2 | c.1684C>T p.R562* | Nonsense Mutation (SNP) | VAF 256/661 reads (39%) | catalogued as rs1173782144; called by muse, mutect2, varscan2
- TRPC3 | c.1045C>T p.L349F (on ENST00000379645 / NM_001366479.2; = p.L276F on NM_003305.2) | Missense Mutation (SNP) | VAF 525/1235 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.824); catalogued as COSV53372232; called by muse, mutect2, varscan2
- WNK2 | c.5483C>T p.A1828V (on ENST00000297954 / NM_001282394.1; = p.A1791V on NM_006648.3) | Missense Mutation (SNP) | VAF 31/284 reads (11%) | SIFT tolerated (0.86); PolyPhen benign (0.081); catalogued as rs1038455859; called by muse, mutect2, varscan2
- ZNF551 | c.831G>T p.K277N | Missense Mutation (SNP) | VAF 445/1194 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.178); catalogued as rs772666359, COSV99989890; called by mutect2, varscan2
- AOC2 | c.1954C>T p.P652S (on ENST00000253799 / NM_009590.4; = p.P625S on NM_001158.5) | Missense Mutation (SNP) | VAF 149/1326 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.542); called by muse, mutect2, varscan2
- DNAH10 | c.2785A>T p.I929F (on ENST00000409039; = p.I868F on NM_207437.3) | Missense Mutation (SNP) | VAF 94/861 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- LOXL2 | c.1339C>T p.R447* | Nonsense Mutation (SNP) | VAF 36/1415 reads (3%) | called by muse, mutect2
- NWD2 | c.4493C>T p.T1498I | Missense Mutation (SNP) | VAF 202/1899 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- PCLO | c.7223C>A p.P2408H | Missense Mutation (SNP) | VAF 125/628 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.505); called by mutect2, varscan2
- STIMATE | c.437T>A p.L146Q | Missense Mutation (SNP) | VAF 38/1020 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.034); called by muse, mutect2
- KIAA1522 | c.330T>C p.S110= (on ENST00000373480 / NM_001198972.2; = p.S169= on NM_020888.3) | Silent (SNP) | VAF 86/793 reads (11%) | called by muse, mutect2, varscan2
- MYO18B | c.7662C>T p.D2554= | Silent (SNP) | VAF 115/1041 reads (11%) | catalogued as rs780180192, COSV59132973; called by muse, mutect2, varscan2
- NBEAL2 | c.6C>T p.A2= | Silent (SNP) | VAF 32/360 reads (9%) | called by muse, mutect2
- PRDM2 | c.3747A>G p.P1249= | Silent (SNP) | VAF 94/1727 reads (5%) | called by muse, mutect2
- CYLD | c.*81G>A | 3'UTR (SNP) | VAF 9/183 reads (5%) | catalogued as rs1275758699; called by muse, mutect2
- ERMN | c.-26C>T | 5'UTR (SNP) | VAF 197/1727 reads (11%) | catalogued as rs998478439; called by mutect2, varscan2
- FCGR2B | c.391+45G>A | Intron (SNP) | VAF 228/642 reads (36%) | catalogued as rs536669911; called by muse, varscan2
- HEXD | c.*68G>A | 3'UTR (SNP) | VAF 23/784 reads (3%) | called by muse, mutect2
- IQCJ-SCHIP1 | c.-26C>A | 5'UTR (SNP) | VAF 40/1496 reads (3%) | called by muse, mutect2
- MEF2A | c.-51C>T | 5'UTR (SNP) | VAF 30/730 reads (4%) | called by muse, mutect2
